Surgical pathology report (de-identified scan), TCGA case TCGA-RW-A68B, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Michigan University, specimen TCGA-RW-A68B-01A (Primary Tumor).

PREVIOUS DIAGNOSIS INQUIRY

REPORT DATE:
NAME:

PATIENT NBR:

PAGE #: 1
SEX: M

ACCESSION:

OPER DATE:

REQ DOC:

PROCEDURE: SPS

VERIFIED BY:

Multinodular goiter. Fine needle aspiration revealed medullary thyroid carcinoma. CT scan showed right adrenal tumor. Right adrenalectomy.

PROCEDURE: SPGD

VERIFIED BY:

1. "Right adrenal." Received fresh is an 8.68 gm adrenal gland measuring 3.5 x 5.1 x 1.0 cm. The adrenal gland is remarkable for a nodular mass which on cut section shows a 1.6 x 1.5 x 1.3 cm tan-brown circumscribed mass surrounded by yellow cortical tissue. Sectioning revealed no other gross abnormality. Central portions of the tumor are submitted for tissue procurement. The remaining nodule and adjacent gland are submitted in 5 cassettes labeled A-E. (nodule , normal gland

PROCEDURE: SPDX

VERIFIED BY:

1. Right adrenal, resection: Pheochromocytoma.

I, the signing staff pathologist, have personally examined and interpreted the slides from this case.

Criteria	lw 4/22/12	Yes	No
Dual/Synchronous History			

Source: NCI Genomic Data Commons file b29b4b65-d7f7-47c7-af69-865f84b62acd (TCGA-RW-A68B.20314F6F-AD56-47B5-973E-57DED5C89B9F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).